Surgical pathology report (de-identified scan), TCGA case TCGA-42-2587, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2587-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN

- A. Omentum
- B. Uterus, cervix, right and left fallopian tubes, ovary
- C. Distal ileum, large bowel, omentum
- D. Anterior abdominal wall, peritoneum

CLINICAL NOTES

PRE-OP DIAGNOSIS: Ovarian cancer

GROSS DESCRIPTION

A. Received is a container labeled with the patient's name, medical record number and "omentum." The specimen consists of a portion of fatty tumor predominantly replaced by tan, firm tumor measuring 8.5 x 7 x 5 cm. in greatest dimensions. The tissue was collected for tissue procurement as requested. Representative sections are submitted in A1-A4.

B. Received fresh and subsequently fixed in formalin labeled "uterus, cervix, right and left tubes and ovaries" is a uterus with attached bilateral adnexae. No discrete left fallopian tube is grossly identified; however, it may be obliterated. The right fallopian tube is grossly identified.

Right

and left ovaries are grossly identified and are markedly distorted and enlarged with tumor. The uterus itself is 93 grams, 7.5 x 5.5

x

4 cm. The anterior wall shows tumor present measuring 5.5 x 2.5 x

2

cm. Otherwise, the serosa and ectocervix are pink-tan smooth and glistening. The specimen is opened to show a pink-tan granular endometrium with an average thickness of 0.1 cm. Multiple intramural fibroids are grossly identified which range from 0.7 cm to 2.7 cm in greatest dimension. These fibroids are calcified.

The

myometrium is pink-tan and slightly trabeculated and has an average thickness of 1.2 cm. The tumor grossly identified on the anterior wall begins to invade the myometrium. The overall thickness of the myometrium with tumor is 2.2 cm. The endocervix is pink-tan smooth to slightly trabeculated with few Nabothian cysts present. The

[page 2 of 4]
GROSS DESCRIPTION

right side adnexa shows a right fallopian tube which is 6.5 x 0.5 cm and is fimbriated. The right ovary is 4.5 x 2.5 x 2.5 cm and shows multiple tumors present within and around. The cut surface of the fallopian tube shows no discrete tumor within; however, the fallopian tube is partially covered with tumor. The left side adnexa shows a 7.5 x 7.5 x 5.5 cm distorted mass. No discrete fallopian tube is grossly identified. This may be obliterated by tumor. The specimen is sectioned to show a tan-pink mottled irregular cut surface grossly consistent with diffuse tumor. No discrete tubular tissue is grossly identified. No additional tissue

is grossly identified in the specimen container. Representative sections of the specimen are submitted as follows: Block 1 - representative cervix; Block 2 - representative endometrium from posterior wall; Block 3 - representative endomyometrium from anterior wall including tumor; Block 4 - representative section of non-calcified fibroid; Block 5 - representative section of right tube with tumor; Blocks 6,7 - representative section of right ovary with tumor; Blocks 8-10 - representative section of left-sided tumor.

C. Received fresh, subsequently fixed in formalin, labeled

"distal ileum, large bowel, omentum." The specimen consists of a subtotal ileostomy and colectomy. Both specimens are predominantly covered with tumor nodules. One segment of the specimen is grossly consistent with a portion of colon. This is

not oriented. Both ends are staples and the specimen is 38 cm. The specimen is inked at both ends arbitrarily and the specimen which are predominantly covered with abundant yellow lobular fat and

tumor and scabrous serosa. The specimen is opened to show pink-tan, smooth glistening mucosa and normal to dilated folds, ranging in circumference from 4.5 cm on the black inked end to 6.5 cm at the blue inked end. Large tumor mass is grossly identified on the surface of the black inked end measuring 6 cm in greatest dimension.

No discrete lesions are grossly identified in the mucosa. However,

GROSS DESCRIPTION

the cut surface of the specimen shows tumor within the muscularis propria of the specimen. Multiple tumors are grossly identified in the fat and may possibly involve lymph node. The second portion of small bowel colon involves 75 cm of small bowel and 45 cm of cecum and colon. Attached to the portion of colon is a large mass of omentum which is caked with tumor. This omentum is 35 x 9 x 6 cm. Again, no discrete tumor is grossly identified in the mucosa of the small bowel or colon. However, the specimen is predominantly covered with tumor throughout and on cut surfaces tumor can be seen involving the muscularis propria of the colon. No discrete tumor

is seen invading the muscularis propria of the small bowel. The

[page 3 of 4]
[REDACTED]

average circumference of the small bowel was 4 cm and the average circumference of the colon is 5.5 cm. Multiple tumor is grossly identified in the cut surface of the fat which may be grossly consistent with possible lymph nodes. No discrete appendix is grossly identified. Representative sections of the specimen are submitted as follows: Block 1 - representative luminal margin of first described segment; block 2, 3 - tumor at muscularis propria and fat; block 4 - representative section of tumor and/or possible positive lymph node; block 5 - representative luminal margins of longer segment; block 6 - representative section of ileocecal valve;

block 7 - site of appendiceal os with subjacent tumor; block 8 - representative section of small bowel with tumor on the surface; block 9, 10 - representative section of colon with tumor possibly involving muscularis propria and fat; block 11 - representative section of omentum; block 12 - representative section of lymph nodes

which are possibly positive. RS-12. [REDACTED]

D. Received fresh and subsequently fixed in formalin labeled "anterior abdominal wall, peritoneum" is a 6.7 x 4.5 x 1 cm yellow-tan-pink rubbery to fatty tissue fragment. The specimen is sectioned to show possible tumor present on cut surface.

Representative sections of the specimen are submitted in two cassettes. [REDACTED]

GROSS DESCRIPTION

[REDACTED]

MICROSCOPIC DESCRIPTION

A. The omentum demonstrates metastatic serous carcinoma, high grade. B. The uterine cervix is without evidence of metastatic disease. The endometrium is atrophic. The serosa and myometrium demonstrate serous carcinoma, high grade, invading into the myometrium. Leiomyomata are present. The right and left ovaries demonstrate high grade serous carcinoma. The right

fallopian tube is involved by serous carcinoma. The left fallopian tube is not grossly identified and may be obliterated by tumor. Possible tubal epithelium is identified histologically, surrounded by tumor.

C. Sections of the distal ileum, colon and omentum demonstrate extensive high grade serous carcinoma, involving the serosal aspects of both large and small bowel and with

invasion through the muscularis propria and up to the mucosal tissues. Perforation through bowel wall is not present. The omentum

is extensively replaced by high grade serous carcinoma (grossly measuring 35 cm). Extensive lymphovascular space invasion is

[page 4 of 4]
identified.

D. The anterior abdominal wall peritoneal biopsy demonstrates high grade serous carcinoma.

5,4,3x2

DIAGNOSIS

A. Omentum, resection
- Serous carcinoma, high grade, 8.5 cm.

B. Uterus, cervix, resection
- No carcinoma identified.
Uterus, endometrium, resection

DIAGNOSIS

- No carcinoma identified.
Uterus, myometrium and serosa, resection
- Serous carcinoma, high grade with extension through serosal surface into myometrial tissues.
Ovary, left, resection
- Serous carcinoma, high grade, 7.5 cm.
Ovary, right, resection
- Serous carcinoma, high grade, 4.5 cm.
Fallopian tube, right, resection
- Serous carcinoma, high grade.
C. Distal ileum, and large bowel, resection
- Extensive involvement by serous carcinoma, high grade with penetration through muscularis propria and into mucosal tissue, no perforation identified.
Omentum, resection
- Serous carcinoma, high grade, 35 cm of tumor.
D. Anterior abdominal wall peritoneum, biopsy

Source: NCI Genomic Data Commons file eab53c2d-c1c8-48ca-8b35-1c003e0e25f6 (TCGA-42-2587.DC4896EF-1797-4796-8869-E9F5D19456D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).